Gene-level copy-number profile of tumor specimen HCM-CSHL-0250-C50-01A from HCMI case HCM-CSHL-0250-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.3 years (22,028 days).
Specimen HCM-CSHL-0250-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba8c13bd-8747-429a-b031-7337f9a67a9b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0250-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/df1f66bd-4b6b-4d2f-8de2-e8c19c834963

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 10,576; copy number 2: 38,456; copy number 3: 6,792; copy number 4: 2,570; copy number 5: 3.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:11,750,586–11,797,258, 1 gene, copy number 5 (within-gene range 4–5): ZC3H7A.
- chr16:11,797,468–11,828,845, 2 genes, copy number 5: AC010654.1, BCAR4.

Autosomal genes at a single copy (total copy number 1): 10,576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
